Surgical pathology report (de-identified scan), TCGA case TCGA-29-1698, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1698-01A (Primary Tumor).

[page 1 of 2]
CLINICAL HISTORY:

Malignant neoplasm ovary = 183.0.

TCGA-29-1698

GROSS EXAMINATION:

A. "Omentum", received fresh and placed in formalin. A 15 x 14 x 3 cm aggregate of lobulated adipose tissue that is largely replaced by firm dense tan-white tissue that occasionally forms focal nodules is received. Representative sections are submitted in block A1-A3.

B. "Right tube and ovary", received fresh and placed in formalin. A 10.4 gram specimen consisting of a 2 x 1.4 x 0.8 cm ovary and attached 4.0 cm long, 0.7 cm in diameter grossly unremarkable fallopian tube is received. The surface of the ovary is tan-white and nodular. Sectioning of the ovary reveals soft tan tissue with focal nodularity. The entire ovary and representative sections of fallopian tube are submitted in blocks B1-B3.

C. "Left tube and ovary", received fresh and placed in formalin. A 10.1 gram specimen consisting of 3 x 1.5 x 1.0 cm ovary and attached 5.0 cm long, 1.0 cm in diameter of segment of fallopian tube. The surface of the ovary is nodular and tan with multifocal friable excrescences. Similar focal tan-yellow excrescences are noted on the surface of the fallopian tube. Sectioning of the fallopian tube reveals that the fimbriated end is filled with firm tan-white homogeneous tissue. Sectioning of the ovary reveals tan-white tissue that is predominantly soft with focal dense firm regions. The entire ovary and representative section of fallopian tube are submitted in blocks C1-C4.

D. "Small bowel nodule", received fresh and placed in formalin. A 2 x 2 x 0.2 cm fragment of firm tan-white tissue is received. The specimen is entirely submitted in block D1.

E. "Right diaphragm", received fresh and placed in formalin. A 6 x 2 x 0.4 cm fragment of smooth tan-white serosa with underlying diffuse red-tan adhesions and excrescences. Representative sections submitted in block E1 and E2.

F. "Transverse colon", received fresh and placed in formalin. A 2.5 x 2.5 x 2.0 cm nodule with a smooth tan-pink surface is received. Sectioning reveals firm tan-white tissue with a necrotic center. Representative sections are submitted in blocks F1 and F2.

G. "Umbilicus", received fresh and placed in formalin. A 6.5 x 3.0 x 3.0 cm aggregate of firm tan-white tissue with tan-brown skin overlying the largest 6.5 x 2.5 x 2.0 cm fragment. The umbilicus is contained within the skin ellipse. Representative sections submitted in blocks D1 and D2.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "OMENTUM" (OMENTECTOMY)

SEROUS CARCINOMA IN FIBROADIPOSE TISSUE.

B. "RIGHT OVARY AND FALLOPIAN TUBE" (SALPINGO-OOPHORECTOMY):

OVARY WITH SEROUS CARCINOMA ON SURFACE. SEE NOTE.

[page 2 of 2]
FALLOPIAN TUBE WITH NO PATHOLOGIC DIAGNOSIS.

C. "LEFT OVARY AND FALLOPIAN TUBE" (SALPINGO-OOPHORECTOMY):

OVARY WITH SEROUS CARCINOMA ON SURFACE. SEE NOTE.

FALLOPIAN TUBE WITH SEROUS CARCINOMA, 6.0 MM IN GREATEST DIMENSION. SEE NOTE.

D. "SMALL BOWEL NODULE" (BIOPSY):

POSITIVE FOR SEROUS CARCINOMA.

E. "RIGHT DIAPHRAGM" (BIOPSY):

SEROUS CARCINOMA IN FIBROCONNECTIVE TISSUE.

F. "TRANSVERSE COLON" (BIOPSY):

POSITIVE FOR SEROUS CARCINOMA.

TCGA-29-1698

G. "UMBILICUS" (EXCISION):

SKIN AND SOFT TISSUE WITH SEROUS CARCINOMA IN SUBCUTANEOUS TISSUE.

NOTE: In the setting of diffuse peritoneal tumor without a dominant ovarian mass, differential considerations include primary peritoneal and primary fallopian tube carcinoma. The presence of a tumor nodule greater than 5 mm within the lumen of the fallopian tube with apparent origin from the mucosa is compatible with a primary fallopian tube carcinoma. The overall grade of the carcinoma is judged to be poorly differentiated, or grade 3.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file bff2d387-43ce-41a7-b06d-5ac84d87f27e (TCGA-29-1698.133F2DF5-6C22-4653-9D2E-F3D5971502B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).